Somatic mutation profile of tumor specimen 0DMBMA from CCDI case PBCAGD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,257 days).
Specimen 0DMBMA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 699e9820-0fc3-43e4-bd44-a820331194de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41d7e941-e9a1-4155-8f2d-e265ce75cb6f

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, Silent 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 495/1107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 239/546 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MUC12 | c.8896G>A p.V2966I (on ENST00000379442; = p.V2823I on NM_001164462.1) | Missense Mutation (SNP) | VAF 124/2762 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as rs768790557; called by muse, mutect2
- MUC12 | c.12145G>A p.V4049I (on ENST00000379442; = p.V3906I on NM_001164462.1) | Missense Mutation (SNP) | VAF 60/990 reads (6%) | SIFT tolerated (0.05); catalogued as rs1306023981; called by muse, mutect2
- TKTL1 | c.253-2A>G p.X85_splice | Splice Site (SNP) | VAF 22/448 reads (5%) | called by muse, mutect2
- SLC6A19 | c.999C>T p.Y333= | Silent (SNP) | VAF 298/739 reads (40%) | catalogued as rs967212443, COSV58671538; called by muse, mutect2, varscan2
- DIP2C | c.85+39177C>T | Intron (SNP) | VAF 112/308 reads (36%) | called by muse, mutect2, varscan2
- SRSF4 | c.-87_-79del | 5'UTR (DEL) | VAF 136/364 reads (37%) | catalogued as rs922008949; called by mutect2, varscan2
